Surgical pathology report (de-identified scan), TCGA case TCGA-62-A46R, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Thoraxklinik at University Hospital Heidelberg, specimen TCGA-62-A46R-01A (Primary Tumor).

1CD-0-3

adenocarcinoma, w/ mixed subtypes
8255/3

Site: lung, lower lobe c34.3

/w 9/24/12

Pathology Report-Summary:

Material:

lung, left, lower lobe: 15.0 x 10.0 x 7.0 cm

tumor: 4.0 x 3.5 x 2.0 cm

Diagnosis:

Adenocarcinoma, mixed subtype (predominantly papillary, partially solid, acinar, BAC)

Infiltration of pleura visceralis

pT2, pN0 (0/20), pMx, G2

Pathologist:

/w 9/24/12

Source: NCI Genomic Data Commons file 76dc6c1c-85fc-42a3-afc0-03a6d94ee539 (TCGA-62-A46R.7AF85E19-CD80-40FD-B0BE-CFFF4B252C0D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).